Somatic mutation profile of tumor specimen BA2628D (aliquot aq-BA2628D) from BEATAML1.0 case 2045, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute erythroid leukaemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.7 years (18,881 days).
Specimen BA2628D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cdba865-cf1f-4ba1-b875-378b43267c03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2725D (Solid Tissue Normal), aliquot aq-BA2725D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98268dc9-5b65-4e3d-a3a1-218cc34ba095

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND4C | c.1202G>A p.G401D | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342614167; called by muse, mutect2
- E4F1 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1268500323; called by muse, mutect2
- IST1 | c.706G>A p.G236R (on ENST00000535424 / NM_001270976.1; = p.G223R on NM_014761.4) | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.241); catalogued as rs754549794; called by muse, mutect2
- PRR23C | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV68827352; called by muse, mutect2
- SLC26A6 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV50839499; called by muse, mutect2
- DNAJC7 | c.1430G>C p.G477A | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- GORASP1 | c.1078A>T p.T360S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PTGER2 | c.355_357del p.F119del | In Frame Del (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2
- LGALS2 | c.105G>T p.L35= | Silent (SNP) | VAF 27/186 reads (15%) | called by muse, varscan2
- USH2A | c.687C>T p.G229= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as rs766740504; called by muse, mutect2, varscan2
- PTPRK | c.693+4460C>T | Intron (SNP) | VAF 20/123 reads (16%) | called by muse, varscan2
- TM9SF4 | c.15+15C>A | Intron (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
